Surgical pathology report (de-identified scan), TCGA case TCGA-FG-8186, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-8186-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Date of Procedure:

Date Received:

Race:

DOB/Sex:

FINAL DIAGNOSIS

A. POSTERIOR MARGIN, BIOPSY:

--INFILTRATING GLIOMA, SEE NOTE.

B. POSTERIOR MEDIAL TUMOR, BIOPSY:

--CEREBRAL CORTEX, NO TUMOR IDENTIFIED.

C. LATERAL SUPERIOR MARGIN, BIOPSY:

--INFILTRATING GLIOMA, SEE NOTE.

D. FRONTAL LOBE, BIOPSY:

--INFILTRATING GLIOMA, SEE NOTE.

E. POSTERIOR MARGIN, BIOPSY:

--INFILTRATING GLIOMA, SEE NOTE.

F. FRONTAL POLE, EXCISION AND G. TUMOR, EXCISION:

--ANAPLASTIC OLIGOASTROCYTOMA (WHO GRADE III), SEE NOTE.

Note: Greater than 90% of the tumor shows features of a WHO grade II oligoastrocytoma, however there is focally increased cellularity and pleomorphism consistent with anaplastic transformation.

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

A: Microscopic: Infiltrating glioma.

B: Microscopic: Cerebral cortex. No definite tumor.

C: Microscopic: Infiltrating glioma.

D: Microscopic: Focal mild hypercellularity consistent with glioma margin.

E: Microscopic: Minimal hypercellularity consistent with glioma margin.

Clinical History:

Right frontal tumor

Specimens Submitted As:

A:POST MARGIN R/O INFILTRATION

B:POST MEDIAL TUMOR R/O INFILTRATION

C:LATERAL SUPERIOR MARGIN

D:FRONTAL LOBE R/O INFILTRATION

E:POSTERIOR MARGIN RULE OUT INFILTRATION

F:FRONTAL POLE

G:TUMOR

Gross Description:

[page 2 of 2]
A: Received fresh for intraoperative evaluation labeled with the patient's name, hospital number and "posterior margin rule out infiltration" are multiple tan-pink soft tissue fragments, 0.5 x 0.5 x 0.1 cm in aggregate. The specimen was entirely submitted for frozen section analysis. The specimen is entirely submitted in one cassette.

B: Received fresh for intraoperative evaluation labeled with the patient's name, hospital number and "posterior medial tumor rule out infiltration" is a tan-pink soft tissue parenchyma 0.5 x 0.5 x 0.2 cm. The specimen was entirely submitted for frozen section analysis. Specimen is entirely submitted one cassette.

C: Received fresh for intraoperative evaluation labeled with the patient's name, hospital number and "lateral superior margin" are multiple tan-pink soft tissue fragments, 1 x 0.7 x 0.4 cm in aggregate. The specimen was entirely submitted for frozen section analysis. The specimen is entirely submitted in one cassette.

D: Received fresh for intraoperative evaluation labeled with the patient's name, hospital number and "frontal lobe rule out infiltration" is a single tan-pink soft tissue fragment, 0.5 x 0.5 x 0.2 cm. The specimen was entirely submitted for frozen section analysis. The specimen is entirely submitted in one cassette.

E: Received fresh for intraoperative evaluation labeled with the patient's name, hospital number and "posterior margin rule out infiltration" is a tan to pink soft tissue fragment that is 0.8 x 0.6 x 0.2 cm. The specimen is entirely submitted for frozen section analysis. The specimen is entirely submitted in one cassette.

F: Received fresh, postfixed in formalin, labeled with the patient's name and number, and "A-frontal pole", is an irregular fragment of opaque white to pink-tan, soft, cerebriform tissue measuring 5.3 x 4.5 x 3.0 cm. Representative sections are submitted in 3 cassettes.

G: Received fresh, postfixed in formalin, labeled with the patient's name and number, and "B- tumor", is an irregular fragment of opaque white to pink-tan, soft, cerebriform tissue measuring 5.0 x 4.8 x 3.8 cm. The specimen is serially sectioned and submitted entirely in 25 cassettes.

Source: NCI Genomic Data Commons file 4282f220-b2f0-4da9-966b-71d3fe1ba332 (TCGA-FG-8186.7E694F9C-B221-40A9-A63A-F5D2DB4E9761.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).